Gene-level copy-number profile of tumor specimen TARGET-10-PATZFF-09A from TARGET case TARGET-10-PATZFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,906 days).
Specimen TARGET-10-PATZFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.04a76ccb-0902-58eb-a240-9ec539775f9f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATZFF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate.
https://portal.gdc.cancer.gov/files/e78ea80c-08ed-47ca-a422-990f8edfcf14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 576; copy number 1: 426; copy number 2: 58,760; copy number 3: 236; copy number 4: 134; copy number 5: 99.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,276,318, 5 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr7:142,598,016–142,779,537, 23 genes: TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:22,438,547–22,459,156, 7 genes: TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr17:18,450,244–18,551,705, 7 genes (within-gene range 0–2): KRT16P4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,762,095–42,281,819, 7 genes, copy number 5: AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr14:105,764,503–106,318,236, 92 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
